FM case AD8795 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/ef3ab91d-d26e-41ed-85da-e9d84b232a80

Female, 20.1 years: Neuroblastoma, NOS (ICD-O-3 9500/3) of the autonomic nervous system; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
